Gene-level copy-number profile of tumor specimen TCGA-22-4591-01A from TCGA case TCGA-22-4591, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 80.1 years (29,250 days).
Specimen TCGA-22-4591-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.9e6083b6-2552-46f2-a2fa-bcdd65f66c8f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-4591-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b2b2bab-705f-441f-ae06-5a33d56de87d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,672; copy number 2: 11,772; copy number 3: 23,306; copy number 4: 10,927; copy number 5: 5,827; copy number 6: 3,194; copy number 7: 70; copy number 8: 519; copy number 9: 165; copy number 10: 503; copy number 11: 420; copy number 12: 230; copy number 13: 10; copy number 14: 10; copy number 15: 97; copy number 16: 22; copy number 17: 28; copy number 18: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-4591-01A-01D-1195-01): tumor purity 0.73, ploidy 3.38, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–22,214,672, 10 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,083 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:45,388,680–71,686,768, 447 genes, copy number 9–13 (within-gene range 3–13) (broad region; genes not listed).
- chr4:55,346,242–56,033,361, 19 genes, copy number 15: SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135.
- chr4:56,097,390–56,097,504, 1 gene, copy number 15: RNA5SP161.
- chr5:58,198–45,895,970, 710 genes, copy number 8–11 (broad region; genes not listed).
- chr6:19,323,428–19,839,080, 1 gene, copy number 8 (within-gene range 3–8): LNC-LBCS.
- chr6:19,438,283–20,212,469, 8 genes, copy number 8: RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1.
- chr7:91,030,149–106,036,432, 383 genes, copy number 8 (broad region; genes not listed).
- chr7:111,726,110–112,206,407, 1 gene, copy number 8 (within-gene range 5–8): DOCK4.
- chr7:111,808,516–119,179,149, 103 genes, copy number 8–10 (broad region; genes not listed).
- chr9:32,293,558–32,454,769, 3 genes, copy number 8: RNA5SP281, SLC25A5P8, ACO1.
- chr10:42,149,310–48,445,820, 180 genes, copy number 7–12 (broad region; genes not listed).
- chr19:27,638,483–33,064,888, 110 genes, copy number 9–18 (within-gene range 3–18) (broad region; genes not listed).
- chr19:38,941,401–41,062,444, 117 genes, copy number 10–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,677. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
